Surgical pathology report (de-identified scan), TCGA case TCGA-R3-A69X, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site CHI-Penrose Colorado, specimen TCGA-R3-A69X-01A (Primary Tumor).

[page 1 of 4]
		Specimen Number:	
		Date of Birth:	Age:
Ordering Physician:	Phone #:	Gender:	Patient location:
Collection date:			
Received date:			

SURGICAL PATHOLOGY

SPECIMEN

- A. URETER - 1. Right distal ureter margin (FS)
- B. URETER - 2. Left distal ureter margin (FS)
- C. LYMPH NODE(S) - 3. Right pelvic lymph nodes
- D. BLADDER - 4. Bladder prostate (fresh for Genome Project)
- E. LYMPH NODE(S) - 5. Left pelvic lymph nodes

CLINICAL INFORMATION

Transitional cell carcinoma bladder

COPY TO:

GROSS DESCRIPTION

The specimens are received in five containers, each labeled with the patient's name

Part A is received fresh for frozen section diagnosis labeled "distal ureter margin right" and consists of a 0.7 x 0.4 x 0.2 cm portion of tan tissue, which is submitted in toto for frozen section diagnosis as FSA1. The frozen section residue is submitted as (A1).

Frozen section diagnosis:

FSA1 - Right distal ureter margin - "No tumor seen."

Examined by

Part B is received fresh for frozen section diagnosis labeled "left distal ureter margin" and consists of a 1.4 x 0.2 x 0.1 cm strip of tan soft tissue, which is submitted in toto for frozen section diagnosis as FSB1. The frozen section residue is submitted as (B1).

Frozen section diagnosis:

FSB1 - Left distal ureter margin - "No tumor seen."

Examined by

*ICD-O-3
Carcinoma, urothelial
8120/3
Site C&CF
Lateral wall of bladder
C67.2
path
Bladder wall NOS
C67.9*

Patient Name

[page 2 of 4]
Part C is received in formalin labeled "right pelvic lymph nodes" and consists of a 5 cm portion of adipose tissue, which contains eight 0.2 cm – 1.7 cm lymph nodes. The lymph nodes are submitted in their entirety as (C1)-(C5).

SLIDE KEY

C1 – four possible lymph nodes

C2-C5 – one bisected lymph node per cassette

Part D is received fresh labeled "bladder/prostate" and consists of a 6 x 5 x 4 cm urinary bladder, in continuity with 2 x 0.5 cm segments of bilateral ureters, symmetrical 4 x 3 x 3 cm prostate gland with bilateral 2 x 1 x 0.5 cm seminal vesicles and a moderate amount of soft perivesicular adipose tissue. There are multiple staples over the mid anterior aspect of the prostate and bladder. The right side of the specimen is inked blue, the left side is black and the mid anterior aspect of the prostate is inked orange. The bladder is opened to disclose a 3 x 1.9 cm ulcer over the right posterior wall, mid posterior walls, extending to left lateral wall and overlying the left ureteral orifice. Sections through the ulcer show a 2.9 x 2.5 x 1.2 cm firm gray-white mass within the left posterior wall and left lateral wall. The mass extends through the bladder wall, 1.6 cm from the left lateral soft tissue margin. The mass does not grossly involve the prostate gland and is located approximately 4.5 cm from the urethral margin. The mass does not grossly involve the right side of the bladder. The remaining bladder mucosa is tan and trabeculated without additional gross lesions. Sections through the prostate gland show a well-defined 0.4 cm white nodule within the right side, near the apex. The remainder of the prostate gland consists of dense tan tissue with focal fine honeycombing. No gross lesions can be identified within the seminal vesicles. No lymph nodes can be identified within the specimen. Fresh tumor is taken for TCGA. Representative sections are submitted as (D1)-(D24).

SLIDE KEY

D1 – right ureter

D2 – left ureter

D3 – right prostate apex margin

D4 – left prostate apex margin

D5 – trigone/prostatic urethra

D6 – trigone/right ureteral orifice

D7 – trigone/left ureteral orifice

D8 – left lateral soft tissue margin

D9-D11 – left lateral bladder lesion

D12 – right posterior bladder

D13 – right lateral bladder

D14 – anterior bladder

D15 – dome of bladder

D16-D19 – right side of prostate, apex to base

D20-D23 – left side of prostate, apex to base

D24 – seminal vesicles

Part E is received in formalin labeled "left pelvic lymph nodes" and consists of a 3 cm aggregate of adipose tissue, which contains a 2.5 cm partially fatty lymph node. The lymph node is submitted in its entirety as (E1).

[page 3 of 4]
MICROSCOPIC DESCRIPTION

Sections examined on multiple H&E-stained slides.

Surgical Pathology Cancer Case Summary, Urinary Bladder – Radical Cystoprostatectomy:

SPECIMEN: Bladder and prostate.

PROCEDURE: Radical cystoprostatectomy.

TUMOR SITE: Invasive tumor is noted along the left posterior and left lateral bladder wall.

TUMOR SIZE: 2.9 x 2.5 x 1.2 cm.

HISTOLOGIC TYPE: Urothelial cell carcinoma.

ASSOCIATED EPITHELIAL LESIONS: Focal carcinoma in situ also present.

HISTOLOGIC GRADE: High grade.

MICROSCOPIC TUMOR EXTENSION: Through detrusor muscle into perivesical fat.

MARGINS: Not involved. Tumor does extend to within 0.7 cm of the left lateral perivesical fat margin.

LYMPHOVASCULAR SPACE INVASION: Present, extensive.

PATHOLOGIC STAGING:

Primary Tumor: pT3, tumor invades perivesical tissue. Grossly, the tumor did appear to extend through the detrusor muscle. However, a true extravesicular mass was not identified. As such, I would favor that this is best categorized as a pT3a rather than pT3b.

Regional Lymph Nodes: pN0, no lymph node metastases.

Number of lymph nodes examined: 7.

Surgical Pathology Cancer Case Summary, Prostate Gland – Radical Prostatectomy:

PROCEDURE: Radical cystoprostatectomy.

PROSTATE SIZE: 4 x 3 x 3 cm. Cannot give accurate weight as the prostate was part of a larger cystoprostatectomy procedure.

LYMPH NODE SAMPLING: Pelvic lymph nodes present.

HISTOLOGIC TYPE: Adenocarcinoma (acinar, not otherwise specified).

HISTOLOGIC GRADE:

Primary Pattern: Grade 3.

Secondary Pattern: Grade 4.

Total Gleason Score: 7 (moderately poorly differentiated).

TUMOR QUANTITATION: Tumor comprises approximately 2% of the submitted prostate tissue.

EXTRAPROSTATIC EXTENSION: Not identified.

SEMINAL VESICLE INVASION: Not identified.

MARGINS: Not involved.

TREATMENT EFFECT: Not identified.

LYMPHOVASCULAR SPACE INVASION: Not identified.

PERINEURAL INVASION: Present.

PATHOLOGIC STAGING:

Primary Tumor: pT2c, bilateral disease.

Regional Lymph Nodes: pN0, no regional lymph node metastasis.

Number of lymph nodes examined: 7, none involved (0/7).

[page 4 of 4]
ADDITIONAL PATHOLOGIC FINDINGS: High-grade prostatic intraepithelial neoplasia.

FINAL DIAGNOSIS

RIGHT DISTAL URETER MARGIN

- Negative for malignancy.

LEFT DISTAL URETER MARGIN

- Negative for malignancy.

RIGHT PELVIC LYMPH NODES, EXCISION

- Six lymph nodes, all negative for metastatic carcinoma (0/6).

BLADDER AND PROSTATE, RADICAL CYSTOPROSTATECTOMY

BLADDER

- High-grade urothelial cell carcinoma with invasion through detrusor muscle into perivesical fat.
- See microscopic/cancer case summary.

PROSTATE

- Prostatic adenocarcinoma, Gleason pattern 3+4=7 (moderately poorly differentiated).
- See microscopic/cancer case summary.

LEFT PELVIC LYMPH NODE, EXCISION

- Single lymph node, negative for metastatic carcinoma (0/1).

CPT CODES: 88331x2, 88305x3, 88307x1, 88309x1

(Electronically signed by) (Final)
Verified:

Source: NCI Genomic Data Commons file ee60d2b8-5ed3-4d57-b278-918c6fff543a (TCGA-R3-A69X.65FF34F8-65D4-4DC8-80D8-FED4DB244F4B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).